Somatic mutation profile of tumor specimen MP2PRT-PAVYXI-TMP1-A (aliquot MP2PRT-PAVYXI-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVYXI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 6.0 years (2,207 days).
Specimen MP2PRT-PAVYXI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a99b60f-0a9e-49ee-8bb0-91cd154680a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVYXI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVYXI-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/736336ad-1fa7-47c3-b797-346e534f0a07

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 6, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 138/300 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APOBR | c.2492G>A p.R831Q (on ENST00000431282; = p.R840Q on NM_018690.4) | Missense Mutation (SNP) | VAF 160/392 reads (41%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs370977343, COSV60491757; called by muse, mutect2, varscan2
- CLTCL1 | c.3544C>T p.R1182C | Missense Mutation (SNP) | VAF 70/399 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as rs782017816; called by muse, mutect2, varscan2
- LRP1 | c.12004G>A p.E4002K | Missense Mutation (SNP) | VAF 93/285 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as rs969670124; called by muse, mutect2, varscan2
- MLLT6 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 123/505 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.216); catalogued as rs543115592; called by muse, mutect2, varscan2
- SLC4A10 | c.356C>A p.T119K | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99762336; called by muse, mutect2
- TRAV2 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 77/462 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs753132865; called by muse, mutect2, varscan2
- DSEL | c.1761T>A p.N587K | Missense Mutation (SNP) | VAF 95/561 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GPR6 | c.902T>C p.V301A | Missense Mutation (SNP) | VAF 108/593 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- GLI2 | c.636C>T p.P212= | Silent (SNP) | VAF 88/281 reads (31%) | catalogued as rs755982802, COSV58043291, COSV58052396; called by muse, mutect2, varscan2
- IGF1R | c.4050C>T p.N1350= | Silent (SNP) | VAF 144/374 reads (39%) | catalogued as rs771019606, COSV51398330; called by muse, mutect2, varscan2
- NTN1 | c.1197G>A p.K399= | Silent (SNP) | VAF 86/275 reads (31%) | catalogued as rs150043655; called by muse, mutect2, varscan2
- ODF3L2 | c.363G>A p.T121= | Silent (SNP) | VAF 118/432 reads (27%) | catalogued as rs994902818; called by muse, mutect2
- PCDHGA6 | c.2265C>T p.H755= | Silent (SNP) | VAF 18/417 reads (4%) | catalogued as rs1293667748; called by muse, mutect2
- USP14 | c.1347G>A p.K449= | Silent (SNP) | VAF 65/406 reads (16%) | called by muse, mutect2, varscan2
- CDH23 | c.3106+32_3106+75del | Intron (DEL) | VAF 55/496 reads (11%) | called by mutect2, pindel
